Somatic mutation profile of tumor specimen 0DLLW6 from CCDI case PBBZPG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.5 years (1,289 days).
Specimen 0DLLW6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7657753f-be2c-4d95-b864-481d8623eb39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLLV1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7529c61-b035-4b5f-a716-930b76811b1c

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 153/719 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- CCDC191 | c.1815C>A p.H605Q | Missense Mutation (SNP) | VAF 66/720 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1290630359, COSV55676569; called by muse, mutect2
- DIS3 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 168/849 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66708362; called by muse, mutect2, varscan2
- KREMEN1 | c.1403A>G p.N468S (on ENST00000407188; = p.N470S on NM_032045.5) | Missense Mutation (SNP) | VAF 24/759 reads (3%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.056); catalogued as rs1208267881, COSV59913315; called by muse, mutect2
- ARHGAP6 | c.2253G>T p.M751I (on ENST00000337414 / NM_013427.3; = p.M548I on NM_013423.3) | Missense Mutation (SNP) | VAF 106/604 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by mutect2, varscan2
- INO80C | c.279C>A p.H93Q | Missense Mutation (SNP) | VAF 364/821 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KANSL1L | c.1538G>C p.G513A | Missense Mutation (SNP) | VAF 103/635 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PTPN13 | c.1007C>G p.T336S | Missense Mutation (SNP) | VAF 193/821 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TECR | c.913C>G p.P305A | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- TTN | c.27552G>T p.E9184D (on ENST00000591111; = p.E8257D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/856 reads (19%) | PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ANHX | c.54G>A p.P18= | Silent (SNP) | VAF 73/386 reads (19%) | catalogued as rs1169541304; called by muse, mutect2, varscan2
- CACNA1F | c.25+30C>A | Intron (SNP) | VAF 69/381 reads (18%) | called by muse, mutect2, varscan2
- CACNA1F | c.25+29C>G | Intron (SNP) | VAF 70/383 reads (18%) | called by muse, mutect2, varscan2
- GTF2H1 | c.838-25A>T | Intron (SNP) | VAF 71/261 reads (27%) | catalogued as rs565808523, COSV99786407; called by muse, mutect2, varscan2
